Gene-level copy-number profile of tumor specimen C3L-04486-54 from CPTAC case C3L-04486, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 45.5 years (16,624 days).
Specimen C3L-04486-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 854c98ca-91f6-47a3-8fdd-eb7a59bcb077.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04486-52 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/13c8290b-cf61-4170-900c-c1af64408d28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 1: 394; copy number 2: 57,817; copy number 3: 10; copy number 5: 2; copy number 7: 1; copy number 8: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:143,905,487–144,419,192, 16 genes (within-gene range 0–2): AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2.
- chr2:25,926,598–25,982,749, 1 gene: KIF3C.
- chr8:12,425,614–12,665,588, 4 genes (within-gene range 0–2): FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr9:68,302,867–68,330,626, 3 genes (within-gene range 0–2): FOXD4L3, AL353608.3, AL353608.1.
- chr14:18,333,726–18,650,966, 17 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:21,997,539–22,552,156, 103 genes (within-gene range 0–2) (broad region; genes not listed).
- chr16:33,577,502–33,622,547, 1 gene (within-gene range 0–2): AC142384.1.
- chr17:46,274,784–46,757,464, 11 genes (within-gene range 0–2): ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11.
- chr21:44,107,373–44,131,181, 1 gene: PWP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:79,278,105–79,278,427, 1 gene, copy number 8: AL355796.1.
- chr6:98,834,574–98,839,458, 1 gene, copy number 9: POU3F2.
- chr7:79,543,911–79,544,853, 1 gene, copy number 7: NUP35P2.
- chr12:38,274,448–38,274,549, 1 gene, copy number 5: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
